Somatic mutation profile of tumor specimen 0DFMJ5 from CCDI case PBBSKG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxoid liposarcoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 15.2 years (5,570 days).
Specimen 0DFMJ5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc283a8e-4505-48b8-b8a7-fe4ab333f25f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFMJ6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66e5d91f-de71-4fd8-8b02-4d3d6d92973d

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, RNA 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MCC | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 440/1182 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PSMC2 | c.334A>T p.I112F | Missense Mutation (SNP) | VAF 380/1031 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ZNF547 | c.915_918del p.F305Lfs*30 | Frame Shift Del (DEL) | VAF 226/692 reads (33%) | called by mutect2, varscan2
- FAM187B | c.414A>G p.K138= | Silent (SNP) | VAF 123/410 reads (30%) | called by muse, mutect2, varscan2
- KRT37 | c.546G>A p.A182= | Silent (SNP) | VAF 102/716 reads (14%) | catalogued as rs778746683, COSV56657409; called by muse, mutect2, varscan2
- AC097637.3 | n.463G>A | RNA (SNP) | VAF 106/304 reads (35%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/225 reads (5%) | called by muse, mutect2
